Somatic mutation profile of tumor specimen MP2PRT-PAPISW-TMP1-A (aliquot MP2PRT-PAPISW-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPISW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,634 days).
Specimen MP2PRT-PAPISW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df27ea1-60bc-4a2c-af33-f0aad8958c01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPISW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPISW-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/678dcaaf-d4f0-4a5d-9c15-3f2e9faa3894

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DRD5 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 364/552 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100431930, COSV58576842; called by muse, varscan2
- PLXNC1 | c.4694G>C p.C1565S | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs368139262; called by muse, mutect2
- PNMA6E | c.1021G>A p.V341M (on ENST00000445091 / NM_001367770.1; = p.V63M on NM_001351293.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1177320037; called by muse, mutect2
- TTC9C | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 103/335 reads (31%) | catalogued as COSV53665765; called by muse, mutect2, varscan2
- KLHDC7A | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 186/567 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NBPF12 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- OXSR1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRRM4 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRO | c.444C>T p.N148= | Silent (SNP) | VAF 86/214 reads (40%) | called by muse, mutect2, varscan2
- SLC9A5 | c.840G>A p.P280= | Silent (SNP) | VAF 32/517 reads (6%) | catalogued as rs573470441; called by muse, mutect2
- FBXW9 | c.381+22G>T | Intron (SNP) | VAF 101/258 reads (39%) | called by mutect2, varscan2
